Somatic mutation profile of tumor specimen 0DA0VG from CCDI case PBBJIA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.6 years (4,976 days).
Specimen 0DA0VG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d09b43d6-6d85-4f13-9eb4-be8c6ae0b0eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA0VH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/946e3b83-a732-43dc-a5dc-0c89d0110d1f

The open-access MAF lists 47 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 11, Intron 3, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 98/208 reads (47%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1014_1015insT p.E339* | Frame Shift Ins (INS) | VAF 240/286 reads (84%) | catalogued as rs1567542146, COSV52669776, COSV52691801; ClinVar: pathogenic; called by mutect2, varscan2
- AHCTF1 | c.5773G>C p.D1925H (on ENST00000366508; = p.D1899H on NM_015446.5) | Missense Mutation (SNP) | VAF 18/486 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV58247965; called by muse, mutect2
- CAGE1 | c.896T>A p.V299D (on ENST00000512086; = p.V163D on NM_205864.3) | Missense Mutation (SNP) | VAF 245/290 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV57077534; called by muse, mutect2, varscan2
- GLRB | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs773896806, COSV104388925; called by muse, mutect2, varscan2
- MCM4 | c.1479T>G p.S493R | Missense Mutation (SNP) | VAF 166/478 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1280395717; called by muse, mutect2, varscan2
- MS4A5 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 36/594 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as rs1392160771; called by muse, mutect2
- NEB | c.6482G>A p.R2161H | Missense Mutation (SNP) | VAF 278/956 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs373778424; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE8A | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 120/549 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs559637860, COSV59638192; called by muse, mutect2, varscan2
- QSER1 | c.1466C>T p.P489L (on ENST00000399302; = p.P618L on NM_001076786.3) | Missense Mutation (SNP) | VAF 202/463 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs781105170; called by muse, mutect2, varscan2
- RIOK1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 133/168 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs375314972; called by muse, mutect2, varscan2
- RRBP1 | c.3388C>G p.Q1130E (on ENST00000377813 / NM_001365613.2; = p.Q697E on NM_004587.3) | Missense Mutation (SNP) | VAF 216/509 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs1004762456; called by muse, mutect2, varscan2
- SRRM1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 22/562 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100104281; called by muse, mutect2
- ZSCAN18 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99559478; called by muse, mutect2
- AC005833.1 | c.1651G>C p.V551L | Missense Mutation (SNP) | VAF 232/543 reads (43%) | SIFT tolerated, low confidence (0.22); called by muse, mutect2, varscan2
- CDC5L | c.2263C>G p.L755V | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2
- CDH12 | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 30/646 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- CLP1 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 27/493 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CLUL1 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 175/363 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DOCK9 | c.134C>T p.P45L (on ENST00000376460 / NM_001366676.2; = p.P46L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/532 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); called by muse, mutect2
- FCGR2A | c.809G>A p.R270K (on ENST00000271450 / NM_001136219.3; = p.R269K on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 290/940 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.347); called by muse, varscan2
- FREM2 | c.8627G>A p.G2876E | Missense Mutation (SNP) | VAF 137/517 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- GBE1 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- IL13RA2 | c.421C>A p.Q141K | Missense Mutation (SNP) | VAF 127/222 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KRTAP23-1 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 208/499 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- LRRC3B | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 259/584 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCM4 | c.1480C>G p.H494D | Missense Mutation (SNP) | VAF 170/490 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMRN2 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 25/871 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- OR8K3 | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PAPPA | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 44/1091 reads (4%) | called by muse, mutect2
- SLC20A2 | c.1084C>A p.H362N | Missense Mutation (SNP) | VAF 37/504 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFYVE9 | c.3656C>G p.S1219C | Missense Mutation (SNP) | VAF 191/416 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRV1 | c.6552C>T p.A2184= | Silent (SNP) | VAF 117/285 reads (41%) | catalogued as rs763086961; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCAS3 | c.2223T>A p.G741= (on ENST00000390652 / NM_001353144.2; = p.G726= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 176/431 reads (41%) | catalogued as rs1311538857; called by muse, mutect2, varscan2
- CERKL | c.1422A>G p.R474= (on ENST00000339098 / NM_001030311.2; = p.R448= on NM_201548.5) | Silent (SNP) | VAF 200/390 reads (51%) | called by muse, mutect2, varscan2
- GPSM3 | c.150G>T p.L50= | Silent (SNP) | VAF 140/165 reads (85%) | called by muse, mutect2, varscan2
- ITPR1 | c.3111A>G p.Q1037= (on ENST00000354582; = p.Q1022= on NM_002222.7) | Silent (SNP) | VAF 20/434 reads (5%) | called by muse, mutect2
- NYNRIN | c.3228G>A p.Q1076= | Silent (SNP) | VAF 169/431 reads (39%) | called by muse, mutect2, varscan2
- OR5H2 | c.78A>T p.P26= | Silent (SNP) | VAF 254/530 reads (48%) | catalogued as rs532361248; called by muse, mutect2, varscan2
- PRR36 | c.3897C>T p.D1299= | Silent (SNP) | VAF 54/158 reads (34%) | called by muse, mutect2, varscan2
- TRIM64B | c.492T>C p.F164= | Silent (SNP) | VAF 33/915 reads (4%) | called by muse, mutect2
- UMODL1 | c.642C>T p.H214= | Silent (SNP) | VAF 223/505 reads (44%) | catalogued as rs1191762097; called by muse, mutect2, varscan2
- ZNF608 | c.4491T>C p.A1497= | Silent (SNP) | VAF 30/712 reads (4%) | called by muse, mutect2
- CABP1 | c.655-3623G>A | Intron (SNP) | VAF 46/634 reads (7%) | catalogued as rs1488321914, COSV56459529; called by muse, mutect2
- LCN15 | c.*21C>T | 3'UTR (SNP) | VAF 268/438 reads (61%) | catalogued as rs377583752, COSV60210233; called by muse, mutect2, varscan2
- RER1 | c.81+377C>T | Intron (SNP) | VAF 15/37 reads (41%) | catalogued as rs1205651145; called by muse, mutect2, varscan2
- TACC2 | c.8393-1840A>C | Intron (SNP) | VAF 119/127 reads (94%) | called by muse, mutect2, varscan2
